Gene-level copy-number profile of tumor specimen ALCH-B3CR-TTP1-A from ALCHEMIST case ALCH-B3CR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 50.9 years (18,583 days).
Specimen ALCH-B3CR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cc761308-135e-4f05-8e47-d4bc754ac71a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3CR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/86e2b89c-4682-4319-80e1-38d1017958a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 579; copy number 1: 587; copy number 2: 29,537; copy number 3: 13,361; copy number 4: 10,022; copy number 5: 2,059; copy number 6: 1,954; copy number 7: 524; copy number 8: 27; copy number 9: 206; copy number 10: 11; copy number 11: 5; copy number 67: 1; copy number 104: 27.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,167,357, 3 genes (within-gene range 0–2): LRRC57P1, Y_RNA, RNU6-904P.
- chr7:114,297,114–114,297,429, 1 gene (within-gene range 0–2): AC073626.2.
- chr10:88,664,441–90,225,443, 45 genes: LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4, KIF20B, LINC00865, MARK2P16, LINC01374, LINC01375, SNRPD2P1, AL139340.1, RN7SKP143.
- chr10:112,888,735–113,353,484, 5 genes: AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P.
- chr10:120,608,580–121,739,730, 14 genes: AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,814 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,562,042–155,660,245, 8 genes, copy number 5 (within-gene range 4–5): ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5.
- chr1:172,370,189–175,743,616, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:183,023,420–185,520,986, 49 genes, copy number 5: LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2.
- chr2:24,491,914–28,751,722, 124 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:38,666,081–39,665,343, 24 genes, copy number 5–6 (within-gene range 4–6): GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1, SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA, CDKL4, MAP4K3, AC007684.1, AC007684.2, MAP4K3-DT.
- chr2:54,972,187–55,112,621, 1 gene, copy number 6 (within-gene range 4–6): RTN4.
- chr2:61,065,871–64,332,801, 73 genes, copy number 5–6 (broad region; genes not listed).
- chr2:69,457,997–70,103,220, 18 genes, copy number 5–6: AAK1, RN7SL604P, SNORA36C, RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1.
- chr2:168,451,324–175,184,607, 127 genes, copy number 5 (broad region; genes not listed).
- chr2:175,842,887–191,032,314, 224 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:191,678,068–201,357,398, 133 genes, copy number 5 (broad region; genes not listed).
- chr3:116,709,235–116,723,581, 2 genes, copy number 5 (within-gene range 4–5): TUSC7, AC108713.1.
- chr3:116,921,328–116,932,238, 2 genes, copy number 5 (within-gene range 4–5): AC069504.1, LINC00901.
- chr3:117,544,205–198,123,232, 1,440 genes, copy number 5–104 (broad region; genes not listed).
- chr7:69,026,433–69,046,803, 1 gene, copy number 6: AC104688.1.
- chr7:69,186,821–70,838,013, 9 genes, copy number 6: AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1.
- chr8:47,736,913–137,105,458, 1,245 genes, copy number 6–9 (broad region; genes not listed).
- chr8:139,508,701–141,968,841, 37 genes, copy number 5–6: AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1, AC104417.1.
- chr8:142,449,430–145,066,685, 160 genes, copy number 5–6 (broad region; genes not listed).
- chr9:71,862,452–72,874,135, 19 genes, copy number 5: ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474.
- chr9:111,996,635–112,175,297, 3 genes, copy number 5 (within-gene range 3–5): RNU6-710P, AL138756.1, SUSD1.
- chr12:12,611,827–12,649,713, 3 genes, copy number 5: CREBL2, RPL21P136, AC008115.4.
- chr12:19,107,854–19,376,400, 4 genes, copy number 5 (within-gene range 3–5): MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P.
- chr14:31,100,112–31,207,804, 3 genes, copy number 5: HECTD1, RPL21P5, RNU6-541P.
- chr14:35,534,164–35,932,325, 9 genes, copy number 5 (within-gene range 3–5): INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2.
- chr14:55,027,230–55,272,075, 8 genes, copy number 5 (within-gene range 4–5): SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2.
- chr19:14,840,466–14,904,138, 7 genes, copy number 6: OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P.
- chr19:15,141,105–15,200,995, 4 genes, copy number 5: OR10B1P, RNU6-782P, NOTCH3, MIR6795.
- chr19:16,352,462–17,255,448, 47 genes, copy number 5 (within-gene range 4–5): AC020917.3, EPS15L1, AC020917.4, AC020917.1, AC020917.2, CALR3, AC008764.1, C19orf44, CHERP, RN7SL146P, AC008764.6, SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1.
- chr19:17,309,518–19,138,513, 100 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:29,606,283–36,913,029, 253 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:38,374,536–39,400,641, 57 genes, copy number 6–7: PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29.
- chr19:53,909,335–56,121,295, 166 genes, copy number 5–10 (broad region; genes not listed).
- chr20:53,799,823–53,875,557, 2 genes, copy number 5: AC006076.1, SUMO1P1.
- chr21:33,324,429–33,359,864, 1 gene, copy number 6 (within-gene range 2–6): IFNAR1.
- chr21:33,403,413–46,691,226, 366 genes, copy number 6 (broad region; genes not listed).
- chr22:17,359,949–17,570,078, 5 genes, copy number 5 (within-gene range 4–5): CECR2, FO681548.1, CLCP1, DNAJA1P6, AC007666.2.
- chr22:40,521,800–40,819,399, 9 genes, copy number 5: MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1, SLC25A17, Z98048.1, JTBP1, MIR4766.
- chr22:45,133,020–45,295,874, 9 genes, copy number 5: NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A.

Autosomal genes at a single copy (total copy number 1): 587. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
